Somatic mutation profile of tumor specimen C3N-01719-04 (aliquot CPT0161990008) from CPTAC case C3N-01719, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.2 years (23,073 days).
Specimen C3N-01719-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15c2d782-652f-400f-b680-1310dfc3cd5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01719-31 (Blood Derived Normal), aliquot CPT0125200002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16491ae2-e7b6-4976-831c-a016a350e1ce

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, RNA 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PARD3B | c.2539G>A p.G847S (on ENST00000406610 / NM_001302769.2; = p.G778S on NM_057177.7) | Missense Mutation (SNP) | VAF 16/611 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as rs919457776; called by muse, mutect2
- AGTR2 | c.503G>A p.W168* | Nonsense Mutation (SNP) | VAF 18/586 reads (3%) | called by muse, mutect2
- FH | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 26/812 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2
- MAGEA6 | c.630A>T p.A210= | Silent (SNP) | VAF 42/1062 reads (4%) | called by muse, mutect2
- FER1L4 | n.4441C>T | RNA (SNP) | VAF 24/734 reads (3%) | catalogued as rs1410454284; called by muse, mutect2
